Somatic mutation profile of tumor specimen HTMCP-03-06-02066-01A (aliquot HTMCP-03-06-02066-01A-01D-4427) from CGCI case HTMCP-03-06-02066, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G4; Age at diagnosis: 48.2 years (17,587 days).
Specimen HTMCP-03-06-02066-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b6af7ab-473e-4990-a300-065cadc133ac.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02066-10A (Blood Derived Normal), aliquot HTMCP-03-06-02066-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52466e59-7133-45b0-bd8e-a7883686a1e6

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS9 | c.1789+1G>T p.X597_splice (on ENST00000242067 / NM_001348036.1; = p.X557_splice on NM_014451.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 33/187 reads (18%) | catalogued as rs201938124, CS055613, COSV54176338; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 25/202 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STAG2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | catalogued as rs1569507848, COSV54351827; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SNW1 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs781514092, COSV55052986; called by mutect2, varscan2
- ZNF546 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752083833; called by muse, mutect2, varscan2
- RAD54L2 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC38 | c.522C>T p.D174= | Silent (SNP) | VAF 29/195 reads (15%) | catalogued as rs148446718; called by muse, mutect2, varscan2
- KLHL1 | c.1584C>A p.P528= | Silent (SNP) | VAF 44/331 reads (13%) | called by muse, mutect2, varscan2
- MYH15 | c.807C>A p.G269= | Silent (SNP) | VAF 27/226 reads (12%) | called by muse, mutect2, varscan2
